Somatic mutation profile of tumor specimen 0DSP26 from CCDI case PBCHIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pancreatoblastoma; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 7.3 years (2,676 days).
Specimen 0DSP26: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20da8b3e-6730-4c04-9f9f-e31fd17b92a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6ef98c0-b35a-4e74-ac40-873e1674dea7

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 59/1037 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); catalogued as rs761729674; called by muse, mutect2
- CTCF | c.1518+1G>T p.X506_splice | Splice Site (SNP) | VAF 108/1304 reads (8%) | catalogued as COSV50463918, COSV50486586; called by muse, mutect2
- LAMA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 153/985 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150637419; called by muse, mutect2, varscan2
- MYBPC3 | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 49/796 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931275955; called by muse, mutect2
- PKD1 | c.3877G>A p.V1293I | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs774353552; called by muse, mutect2, varscan2
- PPM1D | c.1470G>C p.L490F | Missense Mutation (SNP) | VAF 559/1257 reads (44%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.254); catalogued as COSV100010866; called by muse, mutect2, varscan2
- OR10R2 | c.9A>C p.Q3H | Missense Mutation (SNP) | VAF 139/845 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- RP1 | c.6422T>C p.I2141T | Missense Mutation (SNP) | VAF 34/560 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2
- ACSM3 | c.192C>A p.V64= | Silent (SNP) | VAF 127/715 reads (18%) | called by muse, mutect2, varscan2
- MYO5C | c.3633C>T p.I1211= | Silent (SNP) | VAF 38/716 reads (5%) | catalogued as COSV99955036; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 34/219 reads (16%) | called by muse, varscan2
